Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-A8B6, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-A8B6-TTP1-C (Primary Tumor).

[page 1 of 2]
Material description

A) Lower lobe, right lung

Macro description

A) 16 cm pulmonary lobe with pleural area of retraction of about 5 cm corresponding, when you cut, irregular greyish area of about 5 cm of diameter

Micro description

A) Adenocarcinoma 03 with focal papillary areas, infiltrating and passing the visceral pleura, with infiltration of the soft parietal tissues. Margin of bronchial resection free of neoplasia.

Reactive lymphadenitis in the 2 lymph nodes of the lobar hilum

Staging pTNM: pT3NO

CDDP-YP-A8B6-01-PR

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: (R) lung, lower lobe C34.3

ICD-10

C34.11

fw
2/10/12

[page 2 of 2]
Material description

A) Tissue of right hemidiaphragm

Macro description

A) 3 fragments attributable to hemorrhagic and thickened pleura

Histopathological diagnosis

A) Infiltration of adenocarcinoma

Source: NCI Genomic Data Commons file 4ad77bdf-ef32-4dc9-aea5-e0311fe73670 (CDDP-A8B6-TTP1.C372C8A8-BD2C-4C75-BDB6-E1C74C9251B8.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).